Somatic mutation profile of tumor specimen TCGA-CR-7389-01A (aliquot TCGA-CR-7389-01A-11D-2012-08) from TCGA case TCGA-CR-7389, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 55.2 years (20,169 days).
Specimen TCGA-CR-7389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9f7a433-2b08-4b8f-83cc-e3675c8a5351.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7389-10A (Blood Derived Normal), aliquot TCGA-CR-7389-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fbcecae-aba7-4013-9c03-702dadfd40e8

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Frame Shift Del 4, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDUA | c.523T>C p.W175R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs875989946, COSV99926077; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.4395dup p.K1466Qfs*25 | Frame Shift Ins (INS) | VAF 12/117 reads (10%) | catalogued as rs1555195118; ClinVar: likely pathogenic; called by mutect2, pindel
- ACKR1 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV100929589; called by muse, mutect2, varscan2
- ADCY8 | c.2195T>C p.L732S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99652681; called by muse, mutect2
- ADGRD1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as rs141128784; called by muse, mutect2, varscan2
- AFAP1L1 | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99695947; called by muse, mutect2, varscan2
- ALG9 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs782761440, COSV67645172; called by muse, mutect2, varscan2
- C10orf120 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100271651; called by mutect2, varscan2
- C11orf1 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1555163311, COSV99499975; called by muse, mutect2, varscan2
- C6 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV99667225; called by muse, mutect2, varscan2
- CA6 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs201856914, COSV101077577; called by muse, mutect2, varscan2
- CFAP54 | c.5665T>A p.S1889T | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV100733228; called by muse, mutect2, varscan2
- COL2A1 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs777416478, COSV99873421; called by muse, mutect2, varscan2
- CTNNA3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); catalogued as rs756147614, COSV100373630; called by muse, mutect2, varscan2
- CUX1 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as rs782194580, COSV99471829; called by muse, varscan2
- CYTH3 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100641484; called by muse, mutect2, varscan2
- DCC | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100500716; called by muse, mutect2
- DCSTAMP | c.785A>T p.Q262L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99886624; called by muse, mutect2, varscan2
- DDX55 | c.924T>A p.N308K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99434615; called by muse, mutect2, varscan2
- DIAPH1 | c.1142A>T p.D381V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99526714; called by muse, mutect2, varscan2
- DIS3 | c.2036A>C p.H679P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV66708339; called by muse, mutect2, varscan2
- DPP8 | c.1705C>T p.R569C (on ENST00000341861 / NM_001320875.2; = p.R553C on NM_017743.6) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs370549371, COSV100202065, COSV55678963; called by mutect2, varscan2
- FAM118A | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99343603; called by muse, mutect2
- FER1L5 | c.5815A>G p.S1939G (on ENST00000623019; = p.S1903G on NM_001293083.2) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV99383429; called by muse, mutect2, varscan2
- FOXO1 | c.1771G>A p.G591S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.528); catalogued as COSV101092023; called by muse, mutect2, varscan2
- FRYL | c.7637A>G p.E2546G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99977153; called by muse, mutect2
- GNAT3 | c.720G>A p.V240= | Splice Region (SNP) | VAF 15/116 reads (13%) | catalogued as COSV101242397, COSV68068052; called by muse, mutect2, varscan2
- GPR132 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757850974, COSV61678126; called by muse, mutect2, varscan2
- GPR3 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1367942163, COSV100927525; called by muse, mutect2
- GPR39 | c.1286A>T p.E429V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as COSV100257915; called by muse, mutect2, varscan2
- GPRC6A | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV59955197; called by muse, mutect2, varscan2
- HAO1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV101113231; called by muse, mutect2, varscan2
- HIVEP2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99173821; called by muse, mutect2, varscan2
- HPR | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.88); catalogued as COSV99930932; called by muse, mutect2
- IBTK | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100090916; called by muse, mutect2, varscan2
- ITGA8 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959296, COSV65233965; called by muse, varscan2
- KCTD3 | c.1196T>G p.V399G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99379385; called by muse, mutect2
- KDM5A | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV101238906; called by muse, mutect2, varscan2
- MAP1B | c.4787A>G p.Q1596R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99702514; called by muse, mutect2, varscan2
- MOGS | c.2387G>A p.W796* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99270582; called by muse, mutect2, varscan2
- NAP1L3 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV100220433; called by muse, mutect2, varscan2
- NBEA | c.5272G>A p.A1758T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100081283; called by muse, mutect2, varscan2
- NPY2R | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430329178, COSV100279755; called by muse, mutect2, varscan2
- OMD | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV65020129; called by muse, mutect2
- OR5M8 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510692; called by muse, mutect2, varscan2
- OSBP | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99803052; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1349A>T p.D450V (on ENST00000259318 / NM_001136562.3; = p.D681V on NM_007203.5) | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99395331; called by muse, mutect2, varscan2
- PCDHA6 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782509409, COSV65350395; called by muse, mutect2, varscan2
- PCNX4 | c.1359A>G p.V453= (on ENST00000406854 / NM_001330177.2; = p.V219= on NM_022495.5) | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as rs781034559, COSV100470439; called by muse, mutect2, varscan2
- PKHD1L1 | c.4487T>C p.I1496T | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101006297; called by muse, mutect2, varscan2
- PLXDC2 | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV65907228, COSV65907995; called by muse, mutect2
- PTCH2 | c.2196G>C p.R732S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV100942141; called by muse, mutect2, varscan2
- PTPRO | c.3005A>G p.N1002S (on ENST00000281171 / NM_030667.3; = p.N974S on NM_002848.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99840769; called by muse, mutect2, varscan2
- RASGRP4 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs759135742, COSV99498623; called by muse, mutect2, varscan2
- ROBO1 | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101458835; called by muse, mutect2
- RUNX1T1 | c.1597C>T p.R533* (on ENST00000265814 / NM_001198628.1; = p.R506* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV56160521, COSV56166871; called by muse, mutect2, varscan2
- RYR2 | c.14723A>G p.H4908R | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100770974; called by muse, mutect2
- SAE1 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV99538001; called by muse, mutect2, varscan2
- SCN11A | c.2632A>G p.K878E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.489); catalogued as COSV100181783; called by muse, mutect2, varscan2
- SLC46A3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99906361; called by muse, mutect2, varscan2
- SORBS1 | c.805A>T p.S269C (on ENST00000361941 / NM_001034954.2; = p.S237C on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV99528274; called by muse, mutect2, varscan2
- TCTN1 | c.1066G>C p.V356L (on ENST00000551590 / NM_001173975.3; = p.V342L on NM_024549.6) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100886093; called by muse, mutect2, varscan2
- TEP1 | c.5740T>A p.S1914T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV99402586; called by muse, mutect2, varscan2
- TMEM132D | c.2599G>A p.G867S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs1287693062, COSV101242904; called by mutect2, varscan2
- TP53 | c.108del p.S37Pfs*7 | Frame Shift Del (DEL) | VAF 63/194 reads (32%) | catalogued as COSV52756428; called by mutect2, pindel, varscan2
- TTLL8 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1013661412, COSV99838410; called by muse, mutect2, varscan2
- USP54 | c.1882T>C p.F628L | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100161174; called by muse, mutect2
- ZBED9 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV101509278; called by muse, mutect2, varscan2
- ZBTB3 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101188975; called by muse, mutect2, varscan2
- ZBTB44 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.948); catalogued as COSV100777285; called by muse, mutect2, varscan2
- ZNF202 | c.1343A>T p.K448M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV100279067; called by muse, mutect2, varscan2
- ZNF479 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs1554400294, COSV100482791; called by muse, mutect2, varscan2
- ZNF671 | c.152T>C p.F51S | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100235126; called by muse, mutect2, varscan2
- KLF5 | c.389_401del p.L130Sfs*3 | Frame Shift Del (DEL) | VAF 27/167 reads (16%) | called by mutect2, pindel, varscan2
- OR6C65 | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TIGIT | c.126del p.L43Yfs*12 | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | called by mutect2, pindel, varscan2
- TNC | c.5731dup p.R1911Pfs*12 | Frame Shift Ins (INS) | VAF 60/138 reads (43%) | called by mutect2, varscan2
- UNC13C | c.524del p.G175Afs*2 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- ABI3BP | c.2523C>T p.T841= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs1304137764, COSV99427170; called by muse, mutect2, varscan2
- ACSBG1 | c.1062C>T p.D354= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs745876684, COSV99357315; called by muse, mutect2, varscan2
- ADGRA2 | c.3177C>T p.S1059= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99604985; called by mutect2, varscan2
- ARPP21 | c.594T>A p.L198= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99492273; called by muse, mutect2, varscan2
- CACNA1I | c.4251C>A p.I1417= | Silent (SNP) | VAF 16/365 reads (4%) | catalogued as COSV100360580; called by muse, mutect2
- CAPN3 | c.2004C>T p.I668= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV99782723; called by muse, mutect2, varscan2
- DNAH5 | c.5632C>T p.L1878= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV99450755; called by muse, mutect2
- HOMER1 | c.90T>C p.H30= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV99981105; called by muse, mutect2
- IFIT3 | c.534T>C p.I178= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV99260454; called by muse, mutect2, varscan2
- LRIG2 | c.468A>T p.I156= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100743442; called by muse, mutect2, varscan2
- MEGF8 | c.6504G>A p.G2168= (on ENST00000251268 / NM_001271938.2; = p.G2101= on NM_001410.3) | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99236858; called by muse, mutect2, varscan2
- MUC16 | c.17277T>C p.S5759= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV101200170; called by muse, mutect2
- OR8H1 | c.720T>C p.C240= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs576223171, COSV57295395; called by muse, mutect2, varscan2
- PDCD1 | c.684C>T p.F228= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100545441; called by muse, mutect2, varscan2
- POGLUT3 | c.1308A>G p.E436= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs772465165, COSV60211568; called by muse, mutect2, varscan2
- ROR2 | c.1845C>T p.D615= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100995875; called by muse, mutect2, varscan2
- SERPINA4 | c.660G>A p.E220= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as COSV100097231; called by muse, mutect2, varscan2
- SLC46A1 | c.720C>T p.T240= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV100398111; called by muse, mutect2
- SPTA1 | c.1815A>G p.A605= | Silent (SNP) | VAF 15/315 reads (5%) | catalogued as COSV100935108; called by muse, mutect2
- TCTE1 | c.1476T>A p.T492= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV101025459; called by muse, mutect2, varscan2
- ZNF227 | c.969T>C p.S323= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100480449; called by muse, mutect2
- ZNF300 | c.939T>C p.V313= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV99199900; called by muse, mutect2, varscan2
- LINC01559 | n.446G>A | RNA (SNP) | VAF 13/62 reads (21%) | catalogued as rs146660868; called by muse, mutect2, varscan2
